CCDI case PBCEXH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/dbcd37c7-417d-42ac-810d-ade37739813b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 12.4 years (4,525 days).

Biospecimens (3 samples)
- Sample 0DQFIY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DQFJ2, 0DQFJ6 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
